Gene-level copy-number profile of tumor specimen TCGA-DS-A0VL-01A from TCGA case TCGA-DS-A0VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 25.1 years (9,186 days).
Specimen TCGA-DS-A0VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5a7202f1-1877-44e5-aef6-7a870a73d7bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DS-A0VL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28431d78-e4e5-4be2-abd1-e541616bfdc1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 4,094; copy number 3: 2,868; copy number 4: 45,043; copy number 5: 4,463; copy number 6: 1,220; copy number 7: 922; copy number 9: 8; copy number 13: 1,161; copy number 16: 3; copy number 42: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DS-A0VL-01A-21D-A10T-01): tumor purity 0.79, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,201 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,560,334–198,222,513, 1,169 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:98,938,912–102,470,384, 32 genes, copy number 16–42 (within-gene range 2–42): AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
